Somatic mutation profile of tumor specimen TCGA-EJ-7793-01A (aliquot TCGA-EJ-7793-01A-31D-2260-08) from TCGA case TCGA-EJ-7793, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.2 years (17,982 days).
Specimen TCGA-EJ-7793-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5011cef0-c9a8-4333-8851-43919e085bb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7793-10A (Blood Derived Normal), aliquot TCGA-EJ-7793-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f8cb5ba-1c26-4776-8344-047a0eadafa4

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA2D1 | c.2920T>G p.C974G (on ENST00000356253 / NM_001366867.1; = p.C962G on NM_000722.4) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62381920; called by muse, varscan2
- COL12A1 | c.4419G>T p.L1473F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV59398041; called by muse, mutect2
- KIF11 | c.2398C>T p.H800Y | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV53271288; called by muse, mutect2
- OR2M3 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 56/466 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101513479, COSV71759094; called by muse, mutect2, varscan2
- OR4K14 | c.912C>G p.N304K | Missense Mutation (SNP) | VAF 8/214 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100520402, COSV59293107; called by muse, mutect2
- SON | c.6445A>C p.K2149Q | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51661322; called by muse, mutect2, varscan2
- EXOC5 | c.450del p.F150Lfs*7 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by pindel, varscan2
- MMP16 | c.942G>A p.P314= | Silent (SNP) | VAF 28/251 reads (11%) | catalogued as rs750281570, COSV54164710; called by muse, mutect2, varscan2
